Surgical pathology report (de-identified scan), TCGA case TCGA-UU-A93S, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mary Bird Perkins Cancer Center - Our Lady of the Lake, specimen TCGA-UU-A93S-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]	Accession: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: F	Date Collected: [REDACTED]
MRN: [REDACTED]	Date Received: [REDACTED]
Requested by: [REDACTED]	Date Reported: [REDACTED]
Copy to: [REDACTED]	Patient: [REDACTED]

Clinical Data: Right breast mass

FINAL PATHOLOGIC DIAGNOSIS

- Pectoralis muscle:**
Invasive poorly differentiated carcinoma consistent with a breast primary. See synoptic report.
Cautery artifact noted.
- Right breast, mastectomy (2,374 grams):**
Invasive poorly differentiated carcinoma consistent with a breast primary. See synoptic report.

SYNOPTIC REPORT

Procedure:	Mastectomy
Lymph node sampling:	Not performed
Specimen laterality:	Right
Tumor site:	Invasive carcinoma involves all quadrants
Histologic type of invasive carcinoma:	Invasive ductal carcinoma
Tumor size:	19 cm
Histologic grade (Nottingham Histologic Score):	
- Glandular/tubular differentiation:	Score 3
- Nuclear pleomorphism:	Score 3
- Mitotic rate:	Greater than 8 mitoses/mm ² , score 3
- Total overall grade:	9, grade III (G3)
Tumor focality:	Single focus of invasive carcinoma
Ductal carcinoma in-situ:	Not identified
Skin/nipple:	There is ulceration of the skin by tumor. There is dermal lymphatic invasion.
Skeletal muscle:	Carcinoma invades the skeletal muscle.
Margins:	Invasive carcinoma is identified at the deep margin including involvement of the skeletal muscle. Invasive ductal carcinoma is identified within 0.2 cm of the superior skin/soft tissue margin.
Lymphovascular invasion:	Identified including dermal lymphatic invasion
Calcifications:	Present in invasive carcinoma

*ICD-O-3
Carcinoma, infiltrating duct NOS
Site R Breast NOS C50.9
JAN 8/26/14*

[page 2 of 2]
SURGICAL PATHOLOGY REPORT - CONTINUED

Patient: [REDACTED]

Result ID: [REDACTED]

Accession: [REDACTED]

Ancillary studies:

ER, PR and HER-2/neu studies have been ordered on block E and will be reported separately.

Pathologic Tumor Stage:

pT4d NX

Pathologist, Electronic Signature

SPECIMEN(S) SUBMITTED: GROSS DESCRIPTION

1. **Pectoralis muscle:** Received fresh for frozen section diagnosis is a single segment of skeletal muscle with attached fibroadipose tissue and soft tissue measuring 6.5 x 4.0 x 1.5 cm. The specimen is unoriented. One surface is inked black and the opposite surface is inked orange. The specimen is serially sectioned and entirely submitted for frozen section diagnosis in three cassettes. The frozen section remnant is submitted in cassettes A - C.
2. **Right breast:** In formalin labeled with the patient's name and medical record number is a 2374-gram, 26 x 18 x 11 cm right simple mastectomy surfaced by brown skin. The specimen is oriented with a short stitch designated as superior and a long stitch as lateral. The skin surface displays a 19 x 15.5 cm nodular gray-yellow mass involving the entire nipple areolar complex. The nipple is not definitively identified. The mass comes to within 1.5 cm of the inferior skin margin, 2.5 cm of the superior skin margin, 1.8 cm of the lateral skin tip, and 8 cm of the medial skin tip. The superior skin margin is inked blue, the inferior skin margin is inked green, and the deep margin is inked black. Upon sectioning the mass involves all four quadrants and approaches the deep margin. Red-brown muscle is identified at the deep margin, which also appears to be involved by tumor grossly. The cut surface of the mass is pink-gray to tan-yellow, firm, and glistening. The mass occupies approximately 80% of the breast parenchyma. The remaining cut surface displays yellow adipose tissue intermixed with dense tan-white fibroglandular tissue. Representative sections are submitted in nine cassettes as follows: A - B - superior skin margin, C - D - the inferior margin, E - F - mass to include the deep margin, G - the deep margin to include muscle, H - I - the mass to include skin involvement. The specimen is placed in formalin at giving a total formalin fixation time of approximately 8.5 hours.

INTRAOPERATIVE REPORT:

1. Frozen Section Diagnosis: *Carcinoma present, involving skeletal muscle*

CPT CODE(S):

88331, 88307, 88305

ICD-9 CODE(S):

[1749]

FACILITY:

END OF REPORT

Criteria	lv 12/13/13	Yes	No

Source: NCI Genomic Data Commons file 3cbc927b-875e-4e51-b0fa-e13306b2e37d (TCGA-UU-A93S.821ED144-DF12-4E49-ADC7-27FA5E422B83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).